Gene-level copy-number profile of tumor specimen HCM-CSHL-0153-C50-01B from HCMI case HCM-CSHL-0153-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.7 years (22,886 days).
Specimen HCM-CSHL-0153-C50-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d951a179-fbe4-4424-848d-0de6bad5a88b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0153-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,267 have no estimate.
https://portal.gdc.cancer.gov/files/2f2e8abb-7364-4a60-ad95-a8fc4ddbba42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 3,568; copy number 2: 49,850; copy number 3: 1,981; copy number 4: 2,698; copy number 5: 150; copy number 6: 20; copy number 7: 11; copy number 8: 4; copy number 9: 2; copy number 12: 1; copy number 13: 2; copy number 16: 3; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,822,686–12,823,159, 1 gene: LINC01784.
- chr1:13,049,476–13,421,328, 23 genes (within-gene range 0–1): PRAMEF27, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20.
- chr2:89,872,463–89,872,702, 1 gene: IGKV2D-38.
- chr2:90,121,786–90,122,564, 1 gene (within-gene range 0–1): IGKV2D-14.
- chr2:90,359,809–90,367,699, 2 genes: AC233263.1, AC233263.7.
- chr2:91,617,160–91,685,884, 3 genes (within-gene range 0–1): LSP1P4, RNA5SP100, DRD5P1.
- chr4:25,678,850–25,679,020, 1 gene: RPS29P11.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr7:98,617,285–98,629,869, 1 gene: NPTX2.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:144,352,219–144,355,609, 2 genes (within-gene range 0–2): TMEM249, AC233992.2.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–6): CCDC183, AL355987.4.
- chr9:136,803,927–136,808,848, 1 gene (within-gene range 0–3): CCDC183-AS1.
- chr13:112,197,350–112,201,000, 1 gene: LINC01070.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.
- chr14:18,588,274–18,588,315, 1 gene (within-gene range 0–1): CR383656.9.
- chr14:106,723,574–106,762,588, 2 genes: IGHV2-70D, IGHV1-69D.
- chr17:331,205–357,581, 3 genes (within-gene range 0–1): AC129507.1, AC129507.2, AC129507.3.
- chr17:959,034–959,366, 1 gene (within-gene range 0–1): AC036164.1.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:22,331,597–22,332,410, 1 gene: AC087575.1.
- chr17:81,939,645–81,947,601, 2 genes (within-gene range 0–3): MYADML2, AC145207.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:966,482–975,865, 1 gene, copy number 5 (within-gene range 4–5): PLEKHN1.
- chr1:998,962–1,000,172, 1 gene, copy number 13: HES4.
- chr1:1,242,446–1,246,722, 1 gene, copy number 7: C1QTNF12.
- chr1:1,280,436–1,309,609, 2 genes, copy number 5 (within-gene range 4–7): SCNN1D, ACAP3.
- chr1:1,308,597–1,328,896, 3 genes, copy number 5–7: PUSL1, AL139287.1, CPTP.
- chr1:1,352,689–1,361,777, 1 gene, copy number 6: MXRA8.
- chr1:1,378,666–1,379,032, 1 gene, copy number 5: NDUFB4P8.
- chr1:1,420,245–1,434,573, 3 genes, copy number 5–8 (within-gene range 3–8): AL391244.1, TMEM88B, LINC01770.
- chr8:144,314,584–144,336,482, 4 genes, copy number 6–16 (within-gene range 1–16): DGAT1, AC233992.1, MIR6848, SCRT1.
- chr9:136,738,167–136,800,595, 6 genes, copy number 5–7 (within-gene range 0–7): LCN10, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,844,415–136,860,799, 3 genes, copy number 7–9 (within-gene range 3–9): AJM1, PHPT1, MAMDC4.
- chr9:137,188,660–137,204,193, 2 genes, copy number 5 (within-gene range 3–5): SSNA1, TPRN.
- chr10:132,508,394–132,522,449, 2 genes, copy number 6: AL451069.1, LINC01165.
- chr11:1,157,953–1,201,138, 1 gene, copy number 5: MUC5AC.
- chr11:1,469,457–1,572,271, 2 genes, copy number 5–6 (within-gene range 3–6): MOB2, DUSP8.
- chr11:1,760,348–1,762,486, 1 gene, copy number 5: AC068580.3.
- chr11:1,838,981–1,841,680, 1 gene, copy number 5: TNNI2.
- chr14:105,009,573–105,021,083, 1 gene, copy number 5 (within-gene range 2–5): CDCA4.
- chr14:105,093,609–105,100,131, 2 genes, copy number 8: LINC02298, AL512356.4.
- chr14:105,140,982–105,168,824, 2 genes, copy number 6 (within-gene range 4–6): JAG2, MIR6765.
- chr14:105,172,938–105,181,323, 1 gene, copy number 5 (within-gene range 4–5): NUDT14.
- chr14:105,486,317–105,492,267, 2 genes, copy number 6 (within-gene range 2–6): CRIP1, AL928654.3.
- chr14:105,597,691–105,601,728, 1 gene, copy number 6 (within-gene range 2–6): IGHE.
- chr16:396,725–981,318, 50 genes, copy number 5 (within-gene range 2–5): NME4, DECR2, AL023881.1, RAB11FIP3, Y_RNA, AL049542.1, LINC00235, CAPN15, MIR5587, MIR3176, Z97986.1, PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13, AL023882.1, AL031008.1, LMF1, AL031716.1, AL008727.1.
- chr16:981,770–1,105,461, 7 genes, copy number 5–17: SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1.
- chr16:1,148,224–1,351,878, 22 genes, copy number 5: AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2, TPSAB1, TPSD1, AC120498.2, PRSS29P, AC120498.7, AC120498.5, TPSP2, AC120498.4, AC120498.9, UBE2I, AL031714.1, RPS20P2, BAIAP3, TSR3.
- chr16:1,363,205–1,444,556, 6 genes, copy number 5 (within-gene range 4–5): UNKL, AL032819.1, C16orf91, PERCC1, CCDC154, AL032819.2.
- chr16:1,493,344–1,510,457, 1 gene, copy number 5 (within-gene range 4–5): TELO2.
- chr16:1,612,337–1,714,208, 7 genes, copy number 5–7: CRAMP1, Z97652.1, AL031708.1, JPT2, AL031009.1, AL031710.2, AL031710.1.
- chr16:2,253,116–2,273,418, 4 genes, copy number 7: RNPS1, AC009065.4, MIR3677, MIR940.
- chr16:2,339,150–2,426,699, 1 gene, copy number 6 (within-gene range 4–6): ABCA17P.
- chr16:14,071,319–14,266,773, 4 genes, copy number 5: MRTFB, AC130650.2, AC130650.1, TVP23CP2.
- chr17:40,993,430–40,994,164, 1 gene, copy number 5: KRTAP3-3.
- chr19:840,999–856,247, 2 genes, copy number 5: PRTN3, ELANE.
- chr19:984,332–1,378,431, 26 genes, copy number 5 (within-gene range 3–5): WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C, EFNA2, RPS15P9, AC005330.1, PWWP3A.
- chr19:1,383,527–1,435,687, 5 genes, copy number 5 (within-gene range 2–5): NDUFS7, AC005329.3, AC005329.1, GAMT, DAZAP1.
- chr20:62,386,303–62,386,970, 1 gene, copy number 5: AL121832.2.
- chr20:62,410,237–62,427,539, 1 gene, copy number 5: RBBP8NL.
- chr20:62,774,121–62,814,000, 4 genes, copy number 5: LINC00659, MRGBP, OGFR-AS1, OGFR.
- chr20:63,540,810–63,547,504, 2 genes, copy number 6: SRMS, AL121829.2.

Autosomal genes at a single copy (total copy number 1): 3,532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
